Gene-level copy-number profile of tumor specimen TCGA-AC-A8OP-01A from TCGA case TCGA-AC-A8OP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.7 years (26,550 days).
Specimen TCGA-AC-A8OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0a7bfa84-8239-4d2b-8320-3d8a9db2a3ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A8OP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0dcf6c13-1b1e-45b5-a3ad-b5eb7a624625

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 823; copy number 2: 5,136; copy number 3: 17,469; copy number 4: 25,336; copy number 5: 3,425; copy number 6: 2,893; copy number 7: 1,117; copy number 8: 1,419; copy number 9: 1,241; copy number 10: 114; copy number 11: 74; copy number 12: 251; copy number 13: 58; copy number 14: 123; copy number 15: 49; copy number 16: 59; copy number 17: 56; copy number 18: 122; copy number 19: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A8OP-01A-11D-A36I-01): tumor purity 0.42, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,197 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:193,012,250–248,919,946, 1,207 genes, copy number 9 (broad region; genes not listed).
- chr8:55,517,240–55,826,445, 4 genes, copy number 11: AC090200.1, TMEM68, RNA5SP265, TGS1.
- chr8:55,893,595–55,902,855, 2 genes, copy number 11: AC018607.1, SNORA1B.
- chr8:57,994,509–63,014,000, 59 genes, copy number 10–12 (within-gene range 6–12): FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3.
- chr8:62,855,068–66,197,315, 49 genes, copy number 10–19: XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967.
- chr17:18,108,706–21,230,035, 192 genes, copy number 12 (within-gene range 1–12) (broad region; genes not listed).
- chr17:49,505,657–49,574,064, 1 gene, copy number 16 (within-gene range 5–16): AC006487.1.
- chr17:49,544,788–50,631,940, 58 genes, copy number 16: AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1, XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1.
- chr17:50,834,650–63,776,351, 302 genes, copy number 9–18 (within-gene range 7–18) (broad region; genes not listed).
- chr17:64,039,142–74,484,794, 214 genes, copy number 10–19 (broad region; genes not listed).
- chr17:75,441,159–76,807,102, 84 genes, copy number 10–14 (within-gene range 7–14) (broad region; genes not listed).
- chr17:78,214,186–78,577,396, 16 genes, copy number 11 (within-gene range 7–11): BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P.
- chr20:42,072,752–43,304,679, 9 genes, copy number 9 (within-gene range 6–9): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2.

Autosomal genes at a single copy (total copy number 1): 823. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
